Surgical pathology report (de-identified scan), TCGA case TCGA-SP-A6QJ, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site University Health Network, specimen TCGA-SP-A6QJ-01A (Primary Tumor).

[page 1 of 3]
LABORATORY MEDICINE PROGRAM

Surgical Pathology Consultation Report * Addended *

Patient Name: [REDACTED]

MRN: [REDACTED]

DOB: [REDACTED]

Gender: [REDACTED]

HCN: [REDACTED]

Ordering MD: [REDACTED]

Copy To: [REDACTED]

Service: [REDACTED]

Visit #: [REDACTED]

Location: [REDACTED]

Facility: [REDACTED]

Accession #: [REDACTED]

Collected: [REDACTED]

Received: [REDACTED]

Reported: [REDACTED]

Specimen(s) Received

1. Adrenal: right adrenal
2. Adrenal: Left adrenal gland

Diagnosis

1. Composite pheochromocytoma: Adrenal (right) adrenalectomy specimen. See Comment.
2. Clear cell adrenal cortical adenoma with degeneration; no evidence of adrenal medullary hyperplasia: Adrenal (left) adrenalectomy specimen. See Comment.

Comment

The right adrenalectomy specimen reveals a composite pheochromocytoma consisting of pheochromocytoma and ganglioneuroma. Since the gland is almost entirely occupied by the tumor, the assessment of underlying adrenal medullary hyperplasia cannot be performed accurately on this specimen.

The left adrenalectomy specimen shows a clear cell adrenal cortical adenoma with central degeneration. There is no evidence of adrenal medullary hyperplasia. There is also no atrophy of the nontumorous adrenal cortex.

At least 30% of pheochromocytomas and paragangliomas are associated with familial syndromes. Since there is no adrenal medullary hyperplasia in the nontumorous medulla (left adrenal), the possibility of MEN2 is unlikely. The tumor will also be tested for SDHB expression since loss of SDHB expression is regarded as a surrogate marker for familial paraganglioma syndromes caused by any *SDH* mutations. The results of SDHB immunostain will follow as an addendum.

Electronically verified by: [REDACTED]

Clinical History

Bilateral pheochromocytoma

Gross Description

1. The specimen labelled with the patient's name and as "Right Adrenal" consists of a disrupted adrenal gland measuring 8.3 x 6.1 x 2.1 cm and weighing 56.0 g. The specimen is painted with Silver nitrate. A tumor is identified measuring 6.5 x

[page 2 of 3]
Surgical Pathology Consultation Report

6.5 x 2.1 cm and is cystic. There is a small segment of grossly unremarkable adrenal gland measuring 3.0 x 0.8 x 0.2 cm. Tissue is stored frozen.

- 1A tumor with adjacent grossly unremarkable adrenal gland
- 1B-H representative sections of tumor

2. The specimen labelled with the patient's name and as "Left Adrenal" consists of an adrenal gland measuring 5.4 x 3.3 x 2.2 cm and weighing 19.2 g. The specimen is painted with green dye. After removing the surrounding fat the adrenal gland weighs 13.5 g. A tumor is identified measuring 4.7 x 3.2 x 2.0 cm. Tissue is stored frozen.

- 2A-I tumor
- 2J-L remainder of adrenal gland, fatty tissue remaining

Microscopic Description

Synoptic report for specimen 1:

Specimen: Right adrenalectomy specimen

Clinical and Biochemical Features:

- Biochemically Functioning: Metanephrine and adrenaline
- Family history: Not available

Tumor Scintigraphy:

- ¹²³I-metaiodobenzylguanidine scintigraphy: Intense uptake in the right adrenal mass only (Data taken from EPR)

Tumor Location and Size (imaging studies)

- Anatomic location (specify): Right adrenal
- Greatest dimension: 6.0 cm

Received: Fresh

Specimen Integrity: Focally disrupted

Specimen Size: 8.3 x 6.1 x 2.1 cm

Specimen Weight: 56 grams

Tumor Focality: Unifocal

Tumor Size: 6.5 x 6.5 x 2.1 cm

Histologic Features:

- Growth pattern: Nested (alveolar, zellballen) and diffuse pattern
- Composite tumor elements: Present
- Specify: Ganglioneuroma (10%)
- Cytologic variants of Chromaffin and/or Chief cells Epithelioid
- Necrosis: Present, focal (small microscopic foci or single cell necrosis)
- Mitotic rate: <1/10 HPF

Additional Features: Hyaline globules

Encapsulation: Partially encapsulated

Invasive growth:

- Tumor capsule invasion (transcapsular): Superficial
- Adrenal capsule invasion (transcapsular): Not identified
- Local invasion into surrounding tissues: Not identified
- Vascular invasion (intravascular tumor cells associated with thrombus): Not identified
- Lymphatic invasion: Not identified

Surgical margins: Uninvolved

Metastases:

- No lymph nodes are submitted for evaluation
- Distant metastases: No evidence of MIBG uptake except in the right adrenal gland mass

Immunohistochemistry: See Comment

Tumor Type: Composite pheochromocytoma and ganglioneuroma

Associated Lesions: No evidence of adrenal medullary hyperplasia (see comment)

Addendum

Status:

Date Reported:

Addendum Diagnosis

Composite pheochromocytoma with no evidence of SDH mutation based on immunohistochemistry: Adrenal (right) adrenalectomy specimen

[page 3 of 3]
Surgical Pathology Consultation Report

Addendum Comment

The stain for SDHB shows only focal loss of staining; the presence of SDHB immunoreactivity in most of the tumor suggests that this is not an SDH-related lesion.

The MIB-1 labeling index is 5%.

Source: NCI Genomic Data Commons file d63b3e5c-0568-418f-9a61-2ea314a4e58f (TCGA-SP-A6QJ.16332BC8-CDB1-40BC-8AC0-7D154608091D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).